Somatic mutation profile of tumor specimen C3L-00817-01 (aliquot CPT0065870009) from CPTAC case C3L-00817, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 80.8 years (29,511 days).
Specimen C3L-00817-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ad79894b-006a-43f4-8073-2496347c06d7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00817-31 (Blood Derived Normal), aliquot CPT0067710002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2ad31f61-1352-435d-a689-f0e2d0efb19f

The open-access MAF lists 71 somatic variants for this specimen: 46 protein-altering or splice-affecting, 15 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 15, Frame Shift Del 6, Intron 6, In Frame Del 3, 5'UTR 2, Frame Shift Ins 1, Splice Site 1, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD36C | c.2542del p.T848Lfs*12 | Frame Shift Del (DEL) | VAF 26/178 reads (15%) | catalogued as rs1401072818; called by mutect2, pindel, varscan2
- BRINP1 | c.2108T>A p.I703N | Missense Mutation (SNP) | VAF 46/208 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV99775089; called by muse, mutect2, varscan2
- COL28A1 | c.2191C>T p.L731F | Missense Mutation (SNP) | VAF 9/198 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as rs1337816574; called by muse, mutect2
- CYTH3 | c.385A>G p.K129E | Missense Mutation (SNP) | VAF 33/165 reads (20%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as rs1469291191; called by muse, mutect2, varscan2
- FASTK | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 10/242 reads (4%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.019); catalogued as rs1469641261; called by muse, mutect2
- GZMA | c.305C>G p.P102R | Missense Mutation (SNP) | VAF 18/175 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.127); catalogued as COSV57114623; called by muse, mutect2, varscan2
- MMP26 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs775293392; called by muse, varscan2
- SSTR4 | c.415G>T p.V139L | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.939); catalogued as COSV54797987; called by muse, mutect2, varscan2
- TCL1A | c.50G>A p.R17H | Missense Mutation (SNP) | VAF 21/165 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.019); catalogued as COSV68085318; called by muse, mutect2, varscan2
- TGM5 | c.799G>A p.A267T (on ENST00000220420 / NM_201631.4; = p.A185T on NM_004245.4) | Missense Mutation (SNP) | VAF 86/373 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.62); catalogued as rs761166440, COSV55010442; called by muse, varscan2
- TMEM178B | c.840G>T p.R280S | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as COSV73803110; called by muse, mutect2, varscan2
- VHL | c.234dup p.R79Sfs*53 | Frame Shift Ins (INS) | VAF 64/325 reads (20%) | catalogued as COSV56542719, COSV56547343; called by mutect2, pindel, varscan2
- XIRP2 | c.8936C>T p.P2979L (on ENST00000628543; = p.P3154L on NM_152381.6) | Missense Mutation (SNP) | VAF 45/259 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV54694238; called by muse, mutect2, varscan2
- ZFYVE1 | c.1431G>T p.E477D | Missense Mutation (SNP) | VAF 34/183 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.223); catalogued as COSV59611806; called by muse, mutect2, varscan2
- ZNF317 | c.1298T>G p.L433R | Missense Mutation (SNP) | VAF 14/335 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56111808; called by muse, mutect2
- ABCB11 | c.3479C>A p.S1160Y | Missense Mutation (SNP) | VAF 56/328 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AR | c.2094del p.F698Lfs*91 | Frame Shift Del (DEL) | VAF 20/72 reads (28%) | called by mutect2, pindel, varscan2
- ARL6IP5 | c.412T>C p.S138P | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- AZGP1 | c.432_434del p.I145del | In Frame Del (DEL) | VAF 23/154 reads (15%) | called by mutect2, pindel, varscan2
- BEST1 | c.1704_1706del p.K568_D569delinsN | In Frame Del (DEL) | VAF 62/458 reads (14%) | called by mutect2, pindel, varscan2
- C2CD3 | c.6080C>G p.T2027S | Missense Mutation (SNP) | VAF 48/239 reads (20%) | SIFT tolerated (0.7); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CCP110 | c.2551C>G p.Q851E | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CEP192 | c.3208T>A p.L1070M | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by muse, varscan2
- FAM184B | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- GIGYF2 | c.31G>C p.G11R | Missense Mutation (SNP) | VAF 59/351 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- GIGYF2 | c.32G>T p.G11V | Missense Mutation (SNP) | VAF 59/344 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- GMCL1 | c.904A>T p.T302S | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- GPX5 | c.653T>A p.F218Y | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.74); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- HDAC9 | c.834_839del p.N279_N280del | In Frame Del (DEL) | VAF 26/220 reads (12%) | called by mutect2, pindel, varscan2
- HIF1A | c.1614del p.K538Nfs*20 | Frame Shift Del (DEL) | VAF 10/87 reads (11%) | called by mutect2, pindel, varscan2
- HSF1 | c.1161C>A p.H387Q | Missense Mutation (SNP) | VAF 28/183 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IL1RAP | c.65-35_79del p.X22_splice | Splice Site (DEL) | VAF 28/150 reads (19%) | called by mutect2, pindel
- MATN2 | c.43C>G p.Q15E | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- MBD1 | c.1517A>C p.Q506P (on ENST00000269468 / NM_001323950.1; = p.Q450P on NM_015844.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 122/733 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- MTOR | c.4556C>T p.A1519V | Missense Mutation (SNP) | VAF 45/154 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- MYO3A | c.3398G>C p.R1133T | Missense Mutation (SNP) | VAF 52/262 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- NDUFS2 | c.332C>G p.P111R | Missense Mutation (SNP) | VAF 56/262 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- NLRP13 | c.738G>T p.M246I | Missense Mutation (SNP) | VAF 16/177 reads (9%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.678); called by muse, mutect2
- PLCZ1 | c.815_849del p.L272Sfs*14 | Frame Shift Del (DEL) | VAF 54/480 reads (11%) | called by mutect2, pindel
- PMS1 | c.1763A>C p.Q588P | Missense Mutation (SNP) | VAF 61/309 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- SETX | c.45T>G p.I15M | Missense Mutation (SNP) | VAF 89/346 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- SLITRK2 | c.1903T>A p.F635I | Missense Mutation (SNP) | VAF 38/72 reads (53%) | SIFT tolerated (0.33); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- SNX4 | c.915del p.E306Sfs*30 | Frame Shift Del (DEL) | VAF 14/67 reads (21%) | called by mutect2, pindel, varscan2
- TARS1 | c.2011A>T p.N671Y | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TET3 | c.2156G>A p.G719E | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- TNRC18 | c.4689del p.D1564Mfs*9 | Frame Shift Del (DEL) | VAF 47/261 reads (18%) | called by mutect2, pindel, varscan2
- CRB2 | c.1653G>T p.V551= | Silent (SNP) | VAF 26/191 reads (14%) | called by muse, mutect2, varscan2
- F13B | c.684G>A p.K228= | Silent (SNP) | VAF 10/112 reads (9%) | called by muse, mutect2
- GANC | c.864G>A p.S288= | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as rs369762885; called by muse, mutect2, varscan2
- HRC | c.390G>A p.Q130= | Silent (SNP) | VAF 47/203 reads (23%) | called by muse, mutect2, varscan2
- HS3ST3A1 | c.1152C>T p.R384= | Silent (SNP) | VAF 20/138 reads (14%) | catalogued as rs767095174, COSV52372861; called by muse, mutect2, varscan2
- KNDC1 | c.2007G>A p.A669= | Silent (SNP) | VAF 44/188 reads (23%) | catalogued as rs760314836, COSV58845014; called by muse, mutect2, varscan2
- NOMO1 | c.2523C>T p.G841= | Silent (SNP) | VAF 48/318 reads (15%) | catalogued as rs1375264956; called by muse, mutect2, varscan2
- OPRL1 | c.681C>T p.P227= | Silent (SNP) | VAF 68/317 reads (21%) | catalogued as rs745704885, COSV61091777; called by muse, mutect2, varscan2
- OR4N5 | c.378C>A p.I126= | Silent (SNP) | VAF 30/197 reads (15%) | called by muse, mutect2, varscan2
- RPL35 | c.309G>A p.K103= | Silent (SNP) | VAF 39/212 reads (18%) | called by muse, mutect2, varscan2
- SCN5A | c.1356T>C p.G452= | Silent (SNP) | VAF 24/104 reads (23%) | called by muse, mutect2, varscan2
- SORT1 | c.864A>G p.R288= | Silent (SNP) | VAF 17/197 reads (9%) | called by muse, mutect2
- TBR1 | c.1239C>T p.D413= | Silent (SNP) | VAF 11/50 reads (22%) | called by mutect2, varscan2
- UNC13B | c.2088T>A p.V696= | Silent (SNP) | VAF 42/180 reads (23%) | called by muse, mutect2, varscan2
- ZC3H3 | c.1758T>C p.G586= | Silent (SNP) | VAF 20/119 reads (17%) | called by muse, mutect2, varscan2
- APRT | c.-17G>A | 5'UTR (SNP) | VAF 21/119 reads (18%) | catalogued as rs773547053; called by muse, mutect2, varscan2
- C10orf95 | chr10:102454128 C>T | 5'Flank (SNP) | VAF 25/104 reads (24%) | called by muse, mutect2, varscan2
- COPS7A | c.162+1094_162+1096del | Intron (DEL) | VAF 28/123 reads (23%) | called by mutect2, pindel, varscan2
- CXADRP2 | n.302C>A | RNA (SNP) | VAF 34/360 reads (9%) | called by muse, mutect2, varscan2
- DYNC1H1 | c.13006+50C>G | Intron (SNP) | VAF 27/162 reads (17%) | called by muse, mutect2, varscan2
- MCMDC2 | c.604+28T>C | Intron (SNP) | VAF 24/123 reads (20%) | catalogued as rs747057572; called by muse, mutect2, varscan2
- NCR2 | c.644+769G>A | Intron (SNP) | VAF 23/112 reads (21%) | called by muse, mutect2, varscan2
- PTGDS | c.332-24C>G | Intron (SNP) | VAF 31/178 reads (17%) | called by muse, mutect2, varscan2
- TCF3 | c.-2G>C | 5'UTR (SNP) | VAF 11/150 reads (7%) | called by muse, mutect2
- TRAF3IP2 | c.19+3357_19+3362delinsAAATAA | Intron (ONP) | VAF 12/132 reads (9%) | called by mutect2*, pindel
